Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017975-03A.2 (aliquot TARGET-15-SJMPAL017975-03A.2-01D) from TARGET case TARGET-15-SJMPAL017975, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,527 days).
Specimen TARGET-15-SJMPAL017975-03A.2: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bbd6c0f-c732-42fc-8b10-8481ef118cae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017975-10A.1 (Blood Derived Normal), aliquot TARGET-15-SJMPAL017975-10A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1b18231-bedf-41bd-90a8-f6b4c7f6ab88

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, 5'UTR 1, Splice Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2504A>T p.D835V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909646, COSV54042199, COSV54043241, COSV54057031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JADE2 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs767660256; called by muse, varscan2
- SMC5 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs369127149; called by muse, mutect2
- BCL6B | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCORL1 | c.1188dup p.M397Hfs*23 | Frame Shift Ins (INS) | VAF 8/15 reads (53%) | called by pindel, varscan2
- DIP2B | c.3981+1G>A p.X1327_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- DRC3 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- PTPRB | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SLC26A6 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCRIB | c.1728G>T p.L576= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- TXNIP | c.99G>T p.V33= | Silent (SNP) | VAF 41/111 reads (37%) | called by muse, varscan2
- CD44 | c.-13C>A | 5'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- NDE1 | c.*107C>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- STMP1 | c.69+21C>A | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
